Gene-level copy-number profile of tumor specimen TCGA-L9-A5IP-01A from TCGA case TCGA-L9-A5IP, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 40.2 years (14,681 days).
Specimen TCGA-L9-A5IP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.6a347058-4e21-42e6-b41f-997f9f917c01.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L9-A5IP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 829 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d74e871a-b359-401a-b4d6-f9c1d59d19e8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,573; copy number 2: 33,096; copy number 3: 12,201; copy number 4: 8,593; copy number 5: 2,606; copy number 6: 544; copy number 7: 29; copy number 8: 75; copy number 9: 77.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L9-A5IP-01A-21D-A396-01): tumor purity 0.53, ploidy 2.64, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,331 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,953,508–42,035,925, 120 genes, copy number 6–7 (broad region; genes not listed).
- chr1:43,933,320–45,781,957, 82 genes, copy number 6 (broad region; genes not listed).
- chr1:51,577,179–53,738,106, 82 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr1:53,771,018–53,771,153, 1 gene, copy number 6: AL049745.1.
- chr1:64,470,129–64,693,058, 2 genes, copy number 5: CACHD1, MIR4794.
- chr1:66,665,864–66,677,027, 1 gene, copy number 6: AL139147.1.
- chr1:67,307,364–68,449,954, 23 genes, copy number 6: IL12RB2, SERBP1, RNU6-387P, LINC01702, RNU6-1031P, AL590559.1, RN7SL392P, HNRNPCP9, GADD45A, GNG12, RNU7-80P, GNG12-AS1, AL157407.1, DIRAS3, ARL5AP3, WLS, CTBP2P8, MIR1262, RPS7P4, COX6B1P7, ELOCP18, AL139413.1, RPE65.
- chr1:87,620,803–88,685,204, 1 gene, copy number 6 (within-gene range 2–6): PKN2-AS1.
- chr1:88,313,153–90,284,188, 48 genes, copy number 6: AL049861.1, AL445438.1, RN7SL583P, AC093578.1, AC093578.2, RPL36AP10, PKN2, RNU6-125P, ELOCP19, GTF2B, AL445991.1, KYAT3, RBMXL1, GBP3, Y_RNA, GBP1, PTGES3P1, GBP2, AC104459.1, GBP7, GBP4, AC099063.4, AC099063.3, GBP5, AC099063.1, AC099063.2, BX119321.1, GBP6, CAPNS1P1, GBP1P1, AL596214.1, LRRC8B, AC099569.1, LRRC8C-DT, AC093423.2, LRRC8C, AC093423.3, AC093423.1, AC099568.1, AC099568.2, LRRC8D, AL391497.1, RN7SKP272, GEMIN8P4, ZNF326, AL161797.1, AC098656.1, RNU6-695P.
- chr1:114,535,995–114,670,422, 3 genes, copy number 6 (within-gene range 2–6): PKMP1, BCAS2, DENND2C.
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5 (broad region; genes not listed).
- chr2:142,131,178–142,137,830, 1 gene, copy number 7 (within-gene range 4–7): AC078882.1.
- chr10:91,628,442–92,291,078, 14 genes, copy number 6 (within-gene range 4–6): PPP1R3C, GAPDHP28, FAF2P1, TNKS2-AS1, TNKS2, SRP9P1, AL359198.2, FGFBP3, AL359198.1, BTAF1, CPEB3, AL365398.1, SDHCP2, EIF4A1P8.
- chr12:13,437,942–13,982,002, 1 gene, copy number 9 (within-gene range 2–9): GRIN2B.
- chr12:13,459,670–33,718,217, 348 genes, copy number 6–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 584. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
